Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1XZ, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1XZ-01A (Primary Tumor).

[page 1 of 2]
Department of Cancer Pathology

copy No.

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: Multiple organ resection – right breast and axillary tissues

Unit in charge: Central Operating Theatre

Physician in charge:

ref. No.

Material collected on:

Material received on:

Expected time of examination: up to 8 working days

Clinical diagnosis:

10D-0-3

Carcinoma, infiltrating duct, nos 8500/3

Site: breast, nos C50.9 pr 4/12/11

Examination performed on:

Macroscopic description:

Right breast, sized 21 x 15 x 3.5 cm, removed with axillary tissues sized 8 x 8.5 x 3 cm and a skin flap of 21 x 12 cm. Tumour sized 1.2 x 1.1 x 0.8 found in the lower outer quadrant, located 3.5 cm from the upper boundary, 2 cm from the base and 0.6 cm from the skin.

Microscopic description:

Carcinoma ductale invasivum - NHG3 93 + 2 +3: 21 mitoses/10 HPF - visual area 0.55 mm).

Glandular tissue, apart of the tumour, showing lesions of the type mastopathia fibrosa et cystica, lipomatosis.

AXILLARY LYMPH NODES

Metastases carcinomatosae in lymphonodis (No VI/XIV).

Infiltratio capsulae lymphonodorum.

Histopathological diagnosis:

Carcinoma ductale invasivum mammae dextrae. Metastases carcinomatosae in lymphonodis axillae (NO VI/XIV). (NHG3, pT1c, pN2a).

Invasive ductal carcinoma of the right breast. Cancer metastases of the axillary lymph nodes (No VI/XIV).

ICDPA Discrepancy		X

[page 2 of 2]
Compliance validated by:

Examination performed on:

Results of immunohistochemical examination:

Estrogen receptors found in over 75% of neoplastic cell nuclei. No progesterone receptors found in neoplastic cell nuclei. HER2 protein stained with HercepTest™ by DAKO.

Negative reaction in invasive cancerous cells (Score = 1+)

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 8872dd6c-89b7-42a1-bf14-4c0785042b01 (TCGA-D8-A1XZ.1D6EE39C-DE75-4595-943A-CF53873F96BF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).